TARGET case TARGET-15-SJMPAL043511 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/089cea79-fcf4-4db8-be03-ea98dcd1f130

Demographics
Sex at birth: female; Age at index: 9 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 9.8 years (3,573 days); Year of diagnosis: 2014.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 12.9 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL043511-09B: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: AIEOP
- WBC at Diagnosis: 12.9
- Initial Therapy: ALL
- WHO ALAL Classification: NOS (T/B)
- WHO Dx: NOS (T/B)
